Somatic mutation profile of tumor specimen ALCH-ADUI-TTP1-A (aliquot ALCH-ADUI-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADUI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.3 years (21,299 days).
Specimen ALCH-ADUI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8ef2591-af46-4b23-a9a3-93d3e44a30d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADUI-NB1-A (Blood Derived Normal), aliquot ALCH-ADUI-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f2979c0-a909-49ac-915d-bb1ae5df82e6

The open-access MAF lists 433 somatic variants for this specimen: 294 protein-altering or splice-affecting, 82 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 82, Intron 26, Nonsense Mutation 24, RNA 11, 3'UTR 9, Splice Site 8, Splice Region 4, Frame Shift Del 4, 5'UTR 4, 3'Flank 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.226-2A>G p.X76_splice | Splice Site (SNP) | VAF 28/415 reads (7%) | catalogued as rs72656355, CS971669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- EIF1AX | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV65450888, COSV65451589; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 107/762 reads (14%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.1192G>A p.G398R (on ENST00000375888 / NM_001352568.1; = p.G389R on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/483 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as rs759217853, COSV101022558, COSV65519976; called by muse, mutect2, varscan2
- AGBL1 | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767364604, COSV101224391, COSV66858368; called by muse, mutect2
- ALX4 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100241400, COSV61328873; called by muse, mutect2, varscan2
- ANXA10 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.137); catalogued as rs371456571; called by muse, mutect2, varscan2
- AP002748.5 | c.124C>T p.H42Y | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.025); catalogued as rs753698591; called by muse, mutect2, varscan2
- ARID1B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious, low confidence (0); catalogued as rs1212813613; called by muse, mutect2, varscan2
- ASTN1 | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 19/211 reads (9%) | catalogued as COSV99921155; called by muse, mutect2
- BRINP2 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV64181399; called by muse, mutect2
- C22orf42 | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 82/827 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.728); catalogued as rs1203867154; called by muse, mutect2
- CALML5 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs1349085552, COSV66702564; called by muse, mutect2, varscan2
- CAPN2 | c.732C>T p.I244= | Splice Region (SNP) | VAF 65/542 reads (12%) | catalogued as rs371937820; called by muse, mutect2, varscan2
- CDH12 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 69/650 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV66404481; called by muse, mutect2, varscan2
- CDH7 | c.1975G>A p.G659R | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59881280; called by muse, mutect2
- CENPE | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV54385685; called by muse, mutect2, varscan2
- COL19A1 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 96/491 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59586161; called by muse, mutect2, varscan2
- COL5A2 | c.4394G>T p.R1465I | Missense Mutation (SNP) | VAF 69/508 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV66413855; called by muse, mutect2, varscan2
- CSH1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 25/358 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1370328347, COSV60242255; called by muse, mutect2
- CTSG | c.422T>A p.L141Q | Missense Mutation (SNP) | VAF 74/713 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1396480328; called by muse, mutect2, varscan2
- CYP4F22 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 58/592 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as rs1265356032; called by muse, mutect2
- DCAF4L2 | c.612G>T p.L204F | Missense Mutation (SNP) | VAF 70/659 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60480921; called by muse, mutect2, varscan2
- DERA | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70774215; called by muse, mutect2, varscan2
- DNAH2 | c.10048C>T p.P3350S | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs1190232089, COSV66719077; called by muse, mutect2, varscan2
- DNAH5 | c.1988A>G p.Y663C | Missense Mutation (SNP) | VAF 58/502 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371236147; called by muse, mutect2, varscan2
- DPP6 | c.2486C>A p.S829Y (on ENST00000377770 / NM_001364500.2; = p.S767Y on NM_001936.5) | Missense Mutation (SNP) | VAF 49/439 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs1377335340; called by muse, mutect2, varscan2
- DPYSL5 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 49/734 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV56511034; called by muse, mutect2
- DYRK3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.034); catalogued as rs1553418599; called by muse, mutect2
- EIF3A | c.3073G>T p.D1025Y | Missense Mutation (SNP) | VAF 116/947 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1182676002; called by muse, mutect2, varscan2
- ENC1 | c.1077G>C p.W359C | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56630328; called by muse, mutect2, varscan2
- EPB41L4B | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781369450, COSV65797013; called by muse, mutect2, varscan2
- EZR | c.1697A>G p.K566R | Missense Mutation (SNP) | VAF 57/437 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs750026557; called by muse, mutect2, varscan2
- FGFR2 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 59/459 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs372348666, COSV60655200; called by muse, mutect2, varscan2
- FMN1 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs550520649, COSV100308889; called by muse, mutect2, varscan2
- FMN2 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.931); catalogued as rs1362888587; called by muse, mutect2
- FREM2 | c.4515C>A p.D1505E | Missense Mutation (SNP) | VAF 54/578 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54853617; called by muse, mutect2
- GPATCH8 | c.1262A>T p.D421V | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs1280052012; called by muse, mutect2, varscan2
- GPR32 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs754459913, COSV54514655; called by muse, mutect2, varscan2
- HCN1 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 38/1287 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as COSV100298842; called by muse, mutect2
- HERC2 | c.14420C>T p.A4807V | Missense Mutation (SNP) | VAF 87/853 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.714); catalogued as COSV55345244; called by muse, mutect2, varscan2
- HID1 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 23/273 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs1384826278; called by muse, mutect2
- HIVEP2 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268506616; called by muse, mutect2, varscan2
- HK3 | c.2626C>T p.R876C | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as rs534381486; called by muse, mutect2, varscan2
- HNRNPU | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 43/568 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51694667; called by muse, mutect2
- IGF2BP2 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs1011628658; called by muse, mutect2
- INPP4A | c.1870+1G>C p.X624_splice (on ENST00000074304 / NM_001134224.1; = p.X585_splice on NM_001566.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 24/318 reads (8%) | catalogued as COSV50822828; called by muse, mutect2
- ITGA1 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 54/453 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99250803; called by muse, varscan2
- ITK | c.1430G>T p.C477F | Missense Mutation (SNP) | VAF 99/712 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV70065353; called by muse, mutect2, varscan2
- KCNK17 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as rs146747038; called by muse, mutect2, varscan2
- KCNQ3 | c.2078del p.P693Rfs*10 | Frame Shift Del (DEL) | VAF 131/825 reads (16%) | catalogued as COSV66471146; called by mutect2, pindel, varscan2
- KLHL1 | c.1822C>G p.R608G | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64777209; called by muse, mutect2
- KLHL32 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 73/712 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV65115609; called by muse, mutect2, varscan2
- KMT2D | c.9106C>T p.P3036S | Missense Mutation (SNP) | VAF 142/1109 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56408137; called by muse, mutect2, varscan2
- LDB2 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV58765225; called by muse, mutect2, varscan2
- LEPR | c.666C>A p.F222L | Missense Mutation (SNP) | VAF 44/545 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100756191; called by muse, mutect2
- LGR6 | c.1470G>T p.K490N (on ENST00000367278 / NM_001017403.1; = p.K438N on NM_021636.3) | Missense Mutation (SNP) | VAF 47/349 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.71); catalogued as COSV55157497; called by muse, mutect2, varscan2
- LSP1 | c.636-4C>A | Splice Region (SNP) | VAF 43/253 reads (17%) | catalogued as rs773666837; called by muse, mutect2, varscan2
- MMP20 | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 95/744 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52775135; called by muse, mutect2, varscan2
- MSC | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as rs1275652650; called by muse, mutect2, varscan2
- MUC16 | c.39340G>T p.G13114C | Missense Mutation (SNP) | VAF 34/480 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1405443241; called by muse, mutect2
- MUC16 | c.5035G>T p.G1679W | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as COSV67444091; called by muse, mutect2, varscan2
- MYH13 | c.469T>C p.S157P | Missense Mutation (SNP) | VAF 82/674 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1432555412; called by muse, mutect2, varscan2
- MYH8 | c.5611G>A p.V1871I | Missense Mutation (SNP) | VAF 104/756 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as COSV67967737; called by muse, mutect2, varscan2
- MYO7B | c.5408T>C p.I1803T | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs376677890; called by muse, mutect2, varscan2
- NEDD4L | c.1199G>T p.R400L (on ENST00000400345 / NM_001144967.3; = p.R380L on NM_015277.6) | Missense Mutation (SNP) | VAF 37/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1383866958, COSV104376060; called by muse, mutect2
- NETO1 | c.536C>A p.S179Y | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as COSV55001687; called by muse, mutect2, varscan2
- NSD1 | c.6311A>T p.Q2104L | Missense Mutation (SNP) | VAF 112/840 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as CD052494; called by muse, mutect2, varscan2
- OR5D14 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322882888; called by muse, mutect2
- OR8D1 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 25/254 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.071); catalogued as rs1313069138; called by muse, mutect2
- OTUD6B | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 67/430 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); catalogued as rs771021419, COSV53443451; called by muse, mutect2, varscan2
- P4HA3 | c.435C>A p.D145E | Missense Mutation (SNP) | VAF 49/449 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV100525717; called by muse, mutect2, varscan2
- PATJ | c.1559C>A p.P520Q | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV100334453; called by muse, mutect2
- PCDHB8 | c.1399C>A p.P467T | Missense Mutation (SNP) | VAF 100/1987 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50767838; called by muse, mutect2
- PHACTR1 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781724949, COSV60669380; called by muse, mutect2, varscan2
- PIP | c.290C>A p.T97N | Missense Mutation (SNP) | VAF 46/441 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.127); catalogued as COSV99344270; called by muse, mutect2, varscan2
- PKHD1L1 | c.9974A>T p.N3325I | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV65736298; called by muse, mutect2, varscan2
- POLE4 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 19/333 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV99284361; called by muse, mutect2
- PPP1R17 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.948); catalogued as COSV59611543; called by muse, mutect2
- PROCA1 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1244395843; called by muse, mutect2, varscan2
- PSG2 | c.597C>A p.N199K | Missense Mutation (SNP) | VAF 71/649 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs1384730901, COSV61545568; called by muse, mutect2, varscan2
- RING1 | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.5); catalogued as COSV63002283; called by muse, mutect2
- RPS6KA2 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760698571, COSV55827635; called by muse, mutect2, varscan2
- RPS6KA6 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as COSV53120082; called by muse, mutect2, varscan2
- RXFP2 | c.724A>C p.N242H | Missense Mutation (SNP) | VAF 72/608 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1414262527; called by muse, mutect2, varscan2
- SART1 | c.587G>T p.W196L | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1394184213; called by muse, mutect2, varscan2
- SART1 | c.588G>C p.W196C | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs1389894104; called by muse, mutect2, varscan2
- SIPA1L2 | c.4853T>C p.M1618T | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs929389592; called by muse, mutect2, varscan2
- SLC15A3 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs746692063, COSV50027566; called by muse, mutect2, varscan2
- SLIT3 | c.2461G>T p.G821W | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60610581; called by muse, mutect2, varscan2
- SMG1 | c.7468G>A p.G2490S | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs780619657; called by muse, mutect2, varscan2
- SOX30 | c.2090A>G p.Y697C | Missense Mutation (SNP) | VAF 50/331 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1393425807; called by muse, mutect2, varscan2
- SP5 | c.242C>G p.S81W | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV64623297; called by muse, mutect2, varscan2
- SPACA3 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1037370651; called by muse, mutect2, varscan2
- SPANXN4 | c.31A>G p.N11D | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.874); catalogued as rs1219769721; called by muse, mutect2, varscan2
- SPRING1 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs1436214630; called by muse, mutect2, varscan2
- SRGAP3 | c.2506C>T p.Q836* | Nonsense Mutation (SNP) | VAF 160/1018 reads (16%) | catalogued as COSV64530988; called by muse, mutect2, varscan2
- STX1A | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1554616422; called by muse, mutect2
- SULT1C4 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV55598105; called by muse, mutect2
- TBX22 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 87/444 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV64788241; called by muse, varscan2
- THSD4 | c.2129G>T p.R710L | Missense Mutation (SNP) | VAF 96/562 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs775684732, COSV55967055, COSV55967649; called by muse, mutect2, varscan2
- TMEM108 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 35/408 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); catalogued as rs966321812, COSV100419741; called by muse, mutect2
- TPO | c.2533C>A p.P845T | Missense Mutation (SNP) | VAF 110/1080 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV61111715; called by muse, mutect2
- TRIM49B | c.335G>C p.C112S | Missense Mutation (SNP) | VAF 39/416 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347044762; called by muse, mutect2
- UBXN2A | c.401C>G p.S134* | Nonsense Mutation (SNP) | VAF 21/192 reads (11%) | catalogued as COSV58338122; called by muse, mutect2, varscan2
- UNC13C | c.4746G>T p.Q1582H | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV52845053; called by muse, mutect2, varscan2
- USP42 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 107/801 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs775652534, COSV60361935; called by muse, mutect2, varscan2
- VIPR2 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 41/303 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.28); catalogued as rs759681384; called by muse, mutect2, varscan2
- VN1R2 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 91/748 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.105); catalogued as rs774777284; called by muse, mutect2, varscan2
- WDR97 | c.4588G>C p.E1530Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.288); catalogued as rs933270834; called by muse, mutect2, varscan2
- ZFHX3 | c.4197C>A p.Y1399* | Nonsense Mutation (SNP) | VAF 33/209 reads (16%) | catalogued as COSV51708312; called by muse, mutect2, varscan2
- ZFHX4 | c.5158C>A p.P1720T | Missense Mutation (SNP) | VAF 55/475 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99263165; called by muse, mutect2, varscan2
- ZFHX4 | c.5159C>T p.P1720L | Missense Mutation (SNP) | VAF 58/468 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755498809; called by muse, varscan2
- ZKSCAN2 | c.1852G>T p.G618C | Missense Mutation (SNP) | VAF 58/496 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs568858340; called by muse, mutect2, varscan2
- ZNF549 | c.1127G>T p.R376L (on ENST00000376233 / NM_001199295.2; = p.R363L on NM_153263.2) | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs546163846, COSV53725840; called by muse, varscan2
- ZNF717 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 70/853 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as rs77826574, COSV68858044, COSV68863193; called by muse, mutect2
- ZNF729 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 48/558 reads (9%) | catalogued as COSV62605741; called by muse, mutect2
- ZNF761 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV61888069; called by muse, mutect2
- ZNF804A | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 39/452 reads (9%) | catalogued as rs772974941, COSV56437401, COSV56474195; called by muse, mutect2
- ZP4 | c.1376G>A p.C459Y | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765117673, COSV63911608; called by muse, mutect2
- ABCA13 | c.12144G>T p.Q4048H | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB5 | c.3646G>T p.A1216S (on ENST00000404938 / NM_001163941.2; = p.A771S on NM_178559.6) | Missense Mutation (SNP) | VAF 66/642 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AC009093.9 | n.775G>A | Splice Region (SNP) | VAF 55/475 reads (12%) | called by muse, mutect2, varscan2
- ACACA | c.3815G>T p.G1272V | Missense Mutation (SNP) | VAF 100/776 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ACAD10 | c.1777G>T p.A593S | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ADH1B | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALMS1 | c.8875G>T p.D2959Y | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMY2B | c.664A>T p.I222L | Missense Mutation (SNP) | VAF 66/883 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ANHX | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 33/339 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ANKRD60 | c.746G>T p.R249I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, varscan2
- ANKZF1 | c.1877G>T p.R626L | Missense Mutation (SNP) | VAF 38/552 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2
- ANO4 | c.2629T>C p.F877L (on ENST00000392977 / NM_001286615.2; = p.F842L on NM_178826.4) | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- AP4E1 | c.1008G>C p.K336N | Missense Mutation (SNP) | VAF 77/678 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP8A2 | c.3425C>T p.P1142L | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATRNL1 | c.3160G>T p.G1054C | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD1 | c.965G>C p.R322P | Missense Mutation (SNP) | VAF 50/564 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CARD14 | c.1424G>T p.S475I | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CCDC141 | c.4194G>T p.K1398N | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.162); called by muse, mutect2
- CCDC57 | c.2175_2176insA p.G726Rfs*30 | Frame Shift Ins (INS) | VAF 32/331 reads (10%) | called by pindel, varscan2
- CD47 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 41/432 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.273); called by muse, mutect2
- CDHR2 | c.2440C>G p.R814G | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CDX4 | c.456C>A p.S152R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.135); called by muse, varscan2
- CERKL | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 50/672 reads (7%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); called by muse, mutect2
- CFAP91 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 38/448 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.085); called by muse, mutect2
- CLEC4F | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 29/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNGA3 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 64/708 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2
- CNGB1 | c.147G>C p.E49D | Missense Mutation (SNP) | VAF 46/509 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2
- CNNM1 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTN1 | c.1856C>G p.S619C | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CNTNAP3 | c.3179C>G p.S1060C | Missense Mutation (SNP) | VAF 48/1263 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- COL4A1 | c.4078G>T p.G1360W | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ8A | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 50/496 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CROCC | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- CSF2RB | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD3 | c.3601G>T p.G1201C (on ENST00000297405 / NM_001363185.1; = p.G1097C on NM_052900.3) | Missense Mutation (SNP) | VAF 84/1016 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP7B1 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 59/553 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DDX43 | c.1145G>A p.S382N | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMTN | c.690G>A p.M230I | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.8515G>C p.A2839P | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNMT3B | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 30/302 reads (10%) | called by muse, mutect2
- DOCK10 | c.2407C>G p.Q803E | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.307); called by muse, mutect2
- DPPA4 | c.656T>A p.V219E | Missense Mutation (SNP) | VAF 134/546 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DST | c.20542G>T p.A6848S (on ENST00000361203 / NM_001374722.1; = p.A4545S on NM_015548.5) | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.321); called by muse, mutect2
- DYNC1H1 | c.3928G>T p.G1310W | Missense Mutation (SNP) | VAF 61/463 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- DYNC1H1 | c.3929G>T p.G1310V | Missense Mutation (SNP) | VAF 62/463 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- EBNA1BP2 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 63/497 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2S1 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 68/743 reads (9%) | called by muse, mutect2
- EPB41L3 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- EPOR | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- EXOC4 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 19/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EZH1 | c.1615A>T p.M539L | Missense Mutation (SNP) | VAF 36/287 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAT3 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT1 | c.2848G>T p.E950* | Nonsense Mutation (SNP) | VAF 60/670 reads (9%) | called by muse, mutect2
- FOXN1 | c.1729C>G p.P577A | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRG1 | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 103/892 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GFRA3 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 65/411 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- GK3P | c.660T>A p.C220* | Nonsense Mutation (SNP) | VAF 70/671 reads (10%) | called by muse, mutect2, varscan2
- GLI2 | c.2414G>A p.R805H (on ENST00000361492 / NM_001374353.1; = p.R822H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GNB2 | c.787A>C p.M263L | Missense Mutation (SNP) | VAF 65/472 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); called by mutect2, varscan2
- GPR174 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | called by muse, mutect2, varscan2
- GRIK1 | c.2489T>A p.L830Q | Missense Mutation (SNP) | VAF 61/528 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRIN2B | c.3347C>G p.S1116C | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GTF2E1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 38/587 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- HCN1 | c.564G>C p.L188F | Missense Mutation (SNP) | VAF 36/330 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- HEPACAM2 | c.271G>T p.D91Y (on ENST00000394468 / NM_001039372.4; = p.D79Y on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/504 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HFM1 | c.536C>G p.S179C | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- IGKV1-8 | c.251del p.G84Afs*? | Frame Shift Del (DEL) | VAF 90/664 reads (14%) | called by mutect2, varscan2
- IGSF10 | c.6736G>T p.V2246F | Missense Mutation (SNP) | VAF 52/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL17F | c.36C>A p.V12= | Splice Region (SNP) | VAF 62/528 reads (12%) | called by muse, mutect2, varscan2
- IL36A | c.6A>T p.E2D | Missense Mutation (SNP) | VAF 71/690 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMPG1 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 49/570 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2
- IRX5 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KCNC2 | c.1332C>A p.Y444* | Nonsense Mutation (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2, varscan2
- KCNT2 | c.2179A>G p.T727A | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.101); called by muse, mutect2
- KDM5D | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL1 | c.745A>T p.K249* | Nonsense Mutation (SNP) | VAF 58/500 reads (12%) | called by muse, mutect2, varscan2
- KRT2 | c.862-1G>T p.X288_splice | Splice Site (SNP) | VAF 103/815 reads (13%) | called by muse, mutect2, varscan2
- LCE3E | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 68/776 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.257); called by muse, mutect2
- LILRB5 | c.1528C>A p.L510M (on ENST00000449561 / NM_001081442.3; = p.L509M on NM_006840.5) | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); called by muse, mutect2
- LRP1 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 78/611 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC4C | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC4C | c.1591G>T p.G531W | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC8C | c.759A>T p.E253D | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAGEE1 | c.2795A>T p.Q932L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- MATK | c.145C>A p.P49T (on ENST00000310132 / NM_139355.3; = p.P50T on NM_002378.4) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- MCF2 | c.2010G>T p.K670N | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- MCM10 | c.1419-1G>A p.X473_splice (on ENST00000484800 / NM_182751.3; = p.X472_splice on NM_018518.5) | Splice Site (SNP) | VAF 30/242 reads (12%) | called by muse, mutect2, varscan2
- MCOLN3 | c.358A>G p.S120G | Missense Mutation (SNP) | VAF 51/469 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MED21 | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 32/339 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2
- MGARP | c.399A>G p.I133M | Missense Mutation (SNP) | VAF 83/713 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MMP24 | c.1031T>A p.V344D | Missense Mutation (SNP) | VAF 61/563 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- MROH5 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- MUC16 | c.36373G>A p.G12125S | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.638); called by muse, mutect2
- MUC16 | c.16841C>A p.P5614H | Missense Mutation (SNP) | VAF 29/310 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- MYH6 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 65/669 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.077); called by muse, mutect2
- MYOG | c.422A>T p.Q141L | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, varscan2
- NAA16 | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- NAALAD2 | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 64/560 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- NACAD | c.3115G>T p.E1039* | Nonsense Mutation (SNP) | VAF 51/278 reads (18%) | called by muse, mutect2, varscan2
- NEK9 | c.2478C>G p.D826E | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NRXN3 | c.689G>T p.G230V (on ENST00000557594 / NM_001272020.2; = p.G862V on NM_004796.6) | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUAK1 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- NUP214 | c.2652G>T p.Q884H | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NWD2 | c.2471C>A p.P824H | Missense Mutation (SNP) | VAF 52/508 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OCA2 | c.1813G>T p.E605* | Nonsense Mutation (SNP) | VAF 102/965 reads (11%) | called by muse, mutect2, varscan2
- OR13G1 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2G2 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 60/697 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2
- OR52N1 | c.723C>A p.S241R | Missense Mutation (SNP) | VAF 58/454 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR5M1 | c.35T>C p.F12S | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PATE2 | c.109T>C p.Y37H | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- PCDHB11 | c.2126T>A p.V709E | Missense Mutation (SNP) | VAF 96/666 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PGLYRP2 | c.873G>C p.E291D | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.276); called by muse, mutect2
- PHKB | c.3278G>T p.S1093I | Missense Mutation (SNP) | VAF 80/828 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- PNLIPRP2 | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- POLI | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 27/272 reads (10%) | called by muse, mutect2
- PPP1R17 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 20/301 reads (7%) | called by muse, mutect2
- PPP5C | c.1106T>G p.I369S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PPP6R3 | c.2140C>T p.P714S (on ENST00000393800 / NM_001352375.2; = p.P634S on NM_018312.5) | Missense Mutation (SNP) | VAF 208/800 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRF1 | c.344A>T p.E115V | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- PRKCA | c.206-2A>T p.X69_splice | Splice Site (SNP) | VAF 65/393 reads (17%) | called by muse, mutect2, varscan2
- PRKCB | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PRSS57 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2
- PTCD1 | c.1094G>A p.R365K | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTCHD1 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- QRICH1 | c.961dup p.D321Gfs*33 | Frame Shift Ins (INS) | VAF 28/234 reads (12%) | called by mutect2, pindel, varscan2
- RAB4A | c.262G>C p.G88R | Missense Mutation (SNP) | VAF 34/355 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2
- REG3G | c.461-1G>A p.X154_splice | Splice Site (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- REM1 | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 55/701 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RNF122 | c.215A>T p.Y72F | Missense Mutation (SNP) | VAF 68/831 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2
- RP1 | c.1301T>C p.I434T | Missense Mutation (SNP) | VAF 116/906 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTL1 | c.211A>T p.T71S | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- RTL3 | c.984C>A p.C328* | Nonsense Mutation (SNP) | VAF 44/184 reads (24%) | called by muse, mutect2, varscan2
- RYR2 | c.3984dup p.G1329Wfs*5 | Frame Shift Ins (INS) | VAF 56/377 reads (15%) | called by mutect2, pindel, varscan2
- RYR2 | c.5248G>T p.G1750W | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAGE1 | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- SALL2 | c.1578C>G p.N526K | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- SASS6 | c.127-2A>G p.X43_splice | Splice Site (SNP) | VAF 24/193 reads (12%) | called by muse, mutect2, varscan2
- SCAP | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 81/653 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCCPDH | c.903G>T p.R301S | Missense Mutation (SNP) | VAF 34/500 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.02); called by muse, mutect2
- SEMA3E | c.1367A>G p.D456G | Missense Mutation (SNP) | VAF 39/374 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SFTPA2 | c.650C>A p.A217E | Missense Mutation (SNP) | VAF 57/555 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SGO2 | c.3213G>T p.K1071N | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- SKI | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.074); called by muse, mutect2
- SKIDA1 | c.1075_1076del p.H360Pfs*78 | Frame Shift Del (DEL) | VAF 22/211 reads (10%) | called by pindel, varscan2
- SLC4A10 | c.948+1G>A p.X316_splice | Splice Site (SNP) | VAF 34/402 reads (8%) | called by muse, mutect2
- SMPDL3A | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- SNTG1 | c.1046A>G p.D349G | Missense Mutation (SNP) | VAF 81/647 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SP110 | c.2020G>C p.V674L | Missense Mutation (SNP) | VAF 78/936 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- SPHKAP | c.977A>T p.E326V | Missense Mutation (SNP) | VAF 30/355 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); called by muse, mutect2
- SPHKAP | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 30/359 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); called by muse, mutect2
- SPTAN1 | c.2239G>T p.A747S | Missense Mutation (SNP) | VAF 36/596 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.137); called by muse, mutect2
- SVOPL | c.778G>T p.E260* (on ENST00000419765; = p.E108* on NM_174959.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2, varscan2
- SYDE2 | c.1790G>A p.S597N | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SYT7 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 82/712 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TANC2 | c.312A>T p.E104D | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBC1D19 | c.546G>C p.L182F | Missense Mutation (SNP) | VAF 29/246 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TENM2 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 62/567 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMCO3 | c.949A>C p.I317L | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM131L | c.4150G>T p.E1384* | Nonsense Mutation (SNP) | VAF 29/343 reads (8%) | called by muse, mutect2
- TMEM132C | c.3098G>C p.G1033A | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRIM10 | c.164del p.P55Lfs*99 | Frame Shift Del (DEL) | VAF 36/420 reads (9%) | called by mutect2, pindel
- TTC5 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- U2AF1L4 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 55/421 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- USP7 | c.368C>G p.A123G | Missense Mutation (SNP) | VAF 62/469 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- VSTM4 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 33/280 reads (12%) | called by muse, mutect2, varscan2
- ZBTB10 | c.2264G>T p.C755F (on ENST00000430430; = p.C731F on NM_023929.4) | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZBTB49 | c.2018A>C p.D673A | Missense Mutation (SNP) | VAF 74/636 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ZC3H13 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 49/340 reads (14%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2668C>A p.L890M | Missense Mutation (SNP) | VAF 164/836 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF208 | c.3517G>T p.E1173* | Nonsense Mutation (SNP) | VAF 26/364 reads (7%) | called by muse, mutect2
- ZNF549 | c.1062C>G p.I354M (on ENST00000376233 / NM_001199295.2; = p.I341M on NM_153263.2) | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, varscan2
- ZNF630 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF835 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 65/486 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ZNF879 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ABCA12 | c.2826G>A p.E942= (on ENST00000272895 / NM_173076.3; = p.E624= on NM_015657.3) | Silent (SNP) | VAF 65/706 reads (9%) | called by muse, mutect2
- ACOXL | c.1797G>T p.A599= (on ENST00000676595; = p.A569= on NM_001142807.4) | Silent (SNP) | VAF 40/284 reads (14%) | called by muse, mutect2, varscan2
- ACTL6B | c.189G>A p.K63= | Silent (SNP) | VAF 28/272 reads (10%) | catalogued as rs780923884; called by muse, mutect2
- ADAM30 | c.1020G>T p.L340= | Silent (SNP) | VAF 33/331 reads (10%) | catalogued as COSV101023894, COSV101023959; called by muse, mutect2, varscan2
- ADGRB3 | c.1686G>C p.P562= | Silent (SNP) | VAF 51/266 reads (19%) | catalogued as rs148136685; called by muse, mutect2, varscan2
- ADGRG5 | c.1029C>A p.L343= | Silent (SNP) | VAF 49/397 reads (12%) | called by muse, mutect2, varscan2
- AKAP13 | c.5259G>A p.K1753= (on ENST00000394518 / NM_007200.5; = p.K1757= on NM_006738.6) | Silent (SNP) | VAF 32/359 reads (9%) | catalogued as COSV63465806; called by muse, mutect2
- ARHGAP28 | c.75C>T p.A25= | Silent (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- ATP2B4 | c.1248A>G p.V416= | Silent (SNP) | VAF 34/291 reads (12%) | called by muse, mutect2, varscan2
- C7 | c.1794T>A p.T598= | Silent (SNP) | VAF 40/389 reads (10%) | called by muse, mutect2, varscan2
- C7orf57 | c.789C>A p.L263= | Silent (SNP) | VAF 42/297 reads (14%) | called by muse, mutect2, varscan2
- CCDC168 | c.8559T>C p.Y2853= | Silent (SNP) | VAF 45/419 reads (11%) | catalogued as rs1366490100; called by muse, mutect2, varscan2
- CHAD | c.237A>C p.S79= | Silent (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- CLDN5 | c.120C>T p.I40= (on ENST00000618236 / NM_001363066.2; = p.I125= on NM_003277.4) | Silent (SNP) | VAF 37/470 reads (8%) | catalogued as rs151223315; called by muse, mutect2
- COQ4 | c.651G>A p.E217= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2
- CRYGD | c.114G>C p.V38= | Silent (SNP) | VAF 47/468 reads (10%) | called by muse, mutect2, varscan2
- CSMD3 | c.435A>G p.T145= | Silent (SNP) | VAF 143/601 reads (24%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.228G>T p.R76= | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- DDC | c.1206G>T p.V402= | Silent (SNP) | VAF 110/998 reads (11%) | called by muse, mutect2, varscan2
- DNAJC2 | c.1272A>G p.K424= | Silent (SNP) | VAF 27/236 reads (11%) | called by muse, mutect2, varscan2
- DOCK7 | c.3675A>T p.S1225= (on ENST00000635253 / NM_001367561.1; = p.S1194= on NM_033407.3) | Silent (SNP) | VAF 37/343 reads (11%) | catalogued as COSV52005807; called by muse, mutect2, varscan2
- FAM43B | c.771G>T p.A257= | Silent (SNP) | VAF 40/302 reads (13%) | called by muse, varscan2
- FAT3 | c.2022G>T p.G674= | Silent (SNP) | VAF 37/282 reads (13%) | called by muse, mutect2, varscan2
- GABRB3 | c.694C>A p.R232= | Silent (SNP) | VAF 54/600 reads (9%) | catalogued as COSV54689165; called by muse, mutect2
- GINS3 | c.246G>T p.R82= | Silent (SNP) | VAF 55/484 reads (11%) | called by muse, mutect2, varscan2
- GLRA1 | c.264C>A p.V88= | Silent (SNP) | VAF 59/524 reads (11%) | called by muse, mutect2, varscan2
- GRIN2C | c.1653T>C p.Y551= | Silent (SNP) | VAF 19/216 reads (9%) | catalogued as rs764929779; called by muse, mutect2
- GRIN3A | c.132C>T p.I44= | Silent (SNP) | VAF 44/311 reads (14%) | called by muse, mutect2, varscan2
- IGF2BP3 | c.18C>A p.I6= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as COSV51679947; called by muse, mutect2, varscan2
- IGHV3OR16-9 | c.15G>T p.V5= | Silent (SNP) | VAF 34/289 reads (12%) | called by muse, mutect2, varscan2
- IL1RN | c.267G>A p.K89= (on ENST00000409930 / NM_173842.3; = p.K71= on NM_000577.5) | Silent (SNP) | VAF 64/657 reads (10%) | called by muse, mutect2, varscan2
- IL2RB | c.516G>C p.L172= | Silent (SNP) | VAF 66/279 reads (24%) | called by muse, mutect2, varscan2
- KLHL38 | c.669G>A p.R223= | Silent (SNP) | VAF 129/573 reads (23%) | called by muse, mutect2, varscan2
- KRTAP10-9 | c.414G>A p.P138= | Silent (SNP) | VAF 66/578 reads (11%) | catalogued as rs781816025, COSV59963242; called by muse, mutect2, varscan2
- LGALS9B | c.357C>T p.F119= | Silent (SNP) | VAF 40/498 reads (8%) | catalogued as rs772889612; called by muse, varscan2
- LRRC74A | c.732C>A p.I244= | Silent (SNP) | VAF 35/239 reads (15%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2037A>G p.T679= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV58565982; called by muse, mutect2, varscan2
- MICALL2 | c.1578T>G p.S526= | Silent (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- NEDD4L | c.711C>T p.I237= | Silent (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2
- NFKBIZ | c.801G>A p.Q267= | Silent (SNP) | VAF 104/854 reads (12%) | called by muse, mutect2, varscan2
- NPFFR1 | c.879C>T p.I293= | Silent (SNP) | VAF 9/170 reads (5%) | catalogued as rs1004080596; called by muse, mutect2
- NUAK1 | c.1521G>T p.P507= | Silent (SNP) | VAF 52/449 reads (12%) | catalogued as COSV54600560; called by muse, mutect2, varscan2
- NUDT19 | c.354G>A p.L118= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- NUGGC | c.1491G>A p.E497= | Silent (SNP) | VAF 14/415 reads (3%) | called by muse, mutect2
- NUTM1 | c.1242C>A p.I414= | Silent (SNP) | VAF 87/712 reads (12%) | catalogued as COSV59217525; called by muse, mutect2, varscan2
- ONECUT2 | c.99C>T p.H33= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs772182785; called by muse, mutect2, varscan2
- OR14C36 | c.381A>T p.P127= | Silent (SNP) | VAF 24/271 reads (9%) | called by muse, mutect2
- OR5D14 | c.705G>T p.G235= | Silent (SNP) | VAF 30/292 reads (10%) | called by muse, mutect2
- OR5D14 | c.792C>A p.P264= | Silent (SNP) | VAF 42/346 reads (12%) | called by muse, mutect2, varscan2
- OR9Q2 | c.324C>T p.A108= | Silent (SNP) | VAF 57/441 reads (13%) | catalogued as rs1394397398; called by muse, mutect2, varscan2
- PANX3 | c.663C>G p.S221= | Silent (SNP) | VAF 45/455 reads (10%) | called by muse, mutect2, varscan2
- PCDHA10 | c.144G>T p.A48= | Silent (SNP) | VAF 95/746 reads (13%) | catalogued as rs782508103; called by muse, mutect2, varscan2
- PHF20L1 | c.2049A>G p.R683= | Silent (SNP) | VAF 71/308 reads (23%) | catalogued as rs763370657; called by muse, mutect2, varscan2
- PROKR2 | c.999C>T p.F333= | Silent (SNP) | VAF 113/1020 reads (11%) | catalogued as rs138101742; called by muse, mutect2, varscan2
- RAB5A | c.333A>G p.A111= | Silent (SNP) | VAF 36/248 reads (15%) | called by muse, mutect2, varscan2
- RELN | c.5400G>T p.L1800= | Silent (SNP) | VAF 90/843 reads (11%) | called by muse, mutect2, varscan2
- RHAG | c.1056C>T p.G352= | Silent (SNP) | VAF 86/681 reads (13%) | catalogued as rs150024430; called by muse, mutect2, varscan2
- ROPN1 | c.93G>A p.Q31= | Silent (SNP) | VAF 123/515 reads (24%) | catalogued as rs1486422763; called by muse, mutect2, varscan2
- RTP5 | c.888C>G p.L296= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV58319043; called by muse, mutect2, varscan2
- SCN10A | c.2916A>T p.G972= | Silent (SNP) | VAF 19/151 reads (13%) | called by muse, mutect2, varscan2
- SH3BP4 | c.2640G>C p.R880= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- SHBG | c.669C>G p.P223= | Silent (SNP) | VAF 84/656 reads (13%) | catalogued as COSV99352149, COSV99352319; called by muse, mutect2, varscan2
- SLC6A3 | c.741C>A p.V247= | Silent (SNP) | VAF 54/574 reads (9%) | catalogued as COSV99548288; called by muse, mutect2
- SOX14 | c.72C>A p.R24= | Silent (SNP) | VAF 69/536 reads (13%) | called by muse, mutect2, varscan2
- SRGAP3 | c.2505C>A p.L835= | Silent (SNP) | VAF 150/993 reads (15%) | called by muse, mutect2, varscan2
- STPG1 | c.720A>G p.P240= (on ENST00000337248 / NM_001199013.2; = p.P193= on NM_178122.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as rs961751832; called by muse, mutect2
- SYNE1 | c.23883C>T p.A7961= (on ENST00000367255 / NM_182961.4; = p.A7890= on NM_033071.3) | Silent (SNP) | VAF 54/576 reads (9%) | catalogued as rs746786933; called by muse, mutect2
- TBCD | c.2328G>A p.S776= | Silent (SNP) | VAF 13/263 reads (5%) | catalogued as rs777277583; called by muse, mutect2
- TGM6 | c.366C>T p.R122= | Silent (SNP) | VAF 106/887 reads (12%) | catalogued as rs765677732, COSV52482564; called by muse, mutect2, varscan2
- TMTC4 | c.918C>T p.S306= (on ENST00000376234 / NM_001350577.2; = p.S325= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as rs762050345; called by muse, mutect2, varscan2
- TOPBP1 | c.45G>A p.K15= | Silent (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- TRAPPC3L | c.150C>T p.G50= | Silent (SNP) | VAF 44/309 reads (14%) | called by muse, mutect2, varscan2
- TSPAN10 | c.1014G>T p.A338= (on ENST00000574882 / NM_001290212.1; = p.A300= on NM_031945.4) | Silent (SNP) | VAF 19/184 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.32988A>G p.P10996= (on ENST00000591111; = p.P10069= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/496 reads (7%) | called by muse, mutect2
- TTN | c.7866C>A p.I2622= (on ENST00000591111; = p.I2576= on NM_003319.4) | Silent (SNP) | VAF 46/532 reads (9%) | called by muse, mutect2
- UBR3 | c.819A>G p.Q273= | Silent (SNP) | VAF 43/367 reads (12%) | catalogued as rs1467557834; called by muse, mutect2, varscan2
- USH2A | c.13203C>A p.G4401= | Silent (SNP) | VAF 50/534 reads (9%) | called by muse, mutect2
- USP17L1 | c.1155G>A p.V385= | Silent (SNP) | VAF 154/1110 reads (14%) | called by muse, mutect2, varscan2
- UTS2R | c.510G>A p.A170= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV100493349; called by muse, mutect2, varscan2
- WAC | c.1311G>A p.P437= | Silent (SNP) | VAF 20/258 reads (8%) | catalogued as rs1181100433, COSV61566628; called by muse, mutect2
- WNT6 | c.9G>T p.P3= | Silent (SNP) | VAF 27/157 reads (17%) | catalogued as rs775915456; called by muse, mutect2, varscan2
- ZNF676 | c.1038T>C p.C346= (on ENST00000650058; = p.C314= on NM_001001411.3) | Silent (SNP) | VAF 32/606 reads (5%) | catalogued as rs766099109; called by muse, mutect2
- AC022748.1 | n.81C>A | RNA (SNP) | VAF 35/332 reads (11%) | called by muse, mutect2
- ADAMTS8 | c.-116C>A | 5'UTR (SNP) | VAF 10/56 reads (18%) | called by mutect2, varscan2
- AIRE | c.880-175G>A | Intron (SNP) | VAF 88/750 reads (12%) | called by muse, mutect2, varscan2
- AMPD2 | c.91+71G>C | Intron (SNP) | VAF 43/351 reads (12%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.1943-211G>T | Intron (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- ASTN2 | c.3355+4798G>T | Intron (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- AUTS2 | c.661-145353C>T | Intron (SNP) | VAF 27/200 reads (14%) | catalogued as COSV61415595; called by muse, mutect2, varscan2
- B4GALNT1 | c.*2009A>T | 3'UTR (SNP) | VAF 38/326 reads (12%) | called by muse, mutect2, varscan2
- CDH13 | c.45+12308C>A | Intron (SNP) | VAF 37/326 reads (11%) | called by muse, mutect2, varscan2
- DENND1B | c.83-20580C>T | Intron (SNP) | VAF 52/808 reads (6%) | catalogued as rs1558460121, COSV99343971; called by muse, mutect2
- EIF3A | c.1327-358A>G | Intron (SNP) | VAF 32/278 reads (12%) | catalogued as rs756911045; called by muse, mutect2, varscan2
- EPB41L1 | c.1669-2995A>C | Intron (SNP) | VAF 136/494 reads (28%) | called by muse, mutect2, varscan2
- FBXO9 | c.*372G>C | 3'UTR (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2, varscan2
- FGD2 | c.824-13C>T | Intron (SNP) | VAF 47/280 reads (17%) | called by muse, mutect2, varscan2
- FGG | c.*10T>A | 3'UTR (SNP) | VAF 49/331 reads (15%) | called by muse, mutect2, varscan2
- GABRG3 | c.1123-1920C>A | Intron (SNP) | VAF 47/478 reads (10%) | catalogued as rs746819842; called by muse, mutect2, varscan2
- GOLGA6L17P | n.239C>T | RNA (SNP) | VAF 81/625 reads (13%) | called by muse, mutect2, varscan2
- HES6 | c.251-76G>T | Intron (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.1903G>A | RNA (SNP) | VAF 84/702 reads (12%) | called by muse, mutect2, varscan2
- HTR5A | chr7:155069210 C>T | 5'Flank (SNP) | VAF 20/287 reads (7%) | called by muse, mutect2
- KDM2A | c.*434G>C | 3'UTR (SNP) | VAF 59/334 reads (18%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44572102 T>A | 3'Flank (SNP) | VAF 53/470 reads (11%) | called by muse, mutect2, varscan2
- LIMCH1 | c.936-7628G>A | Intron (SNP) | VAF 52/444 reads (12%) | called by muse, mutect2, varscan2
- METTL2B | c.669+324T>C | Intron (SNP) | VAF 17/236 reads (7%) | called by muse, mutect2
- MIR487B | n.17G>T | RNA (SNP) | VAF 76/524 reads (15%) | called by muse, varscan2
- MIR487B | n.18G>A | RNA (SNP) | VAF 78/539 reads (14%) | called by muse, mutect2, varscan2
- MIR7162 | chr10:30365227 C>A | 3'Flank (SNP) | VAF 37/431 reads (9%) | called by muse, mutect2
- MIR7162 | chr10:30365228 C>A | 3'Flank (SNP) | VAF 36/428 reads (8%) | called by muse, mutect2
- MTMR1 | c.1057-1126G>T | Intron (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- MTNR1A | c.*17G>T | 3'UTR (SNP) | VAF 51/412 reads (12%) | catalogued as rs546026620, COSV100208212, COSV100208354; called by muse, mutect2, varscan2
- MTR | c.503-1039A>T | Intron (SNP) | VAF 55/398 reads (14%) | called by muse, mutect2, varscan2
- NDRG1 | c.*3G>A | 3'UTR (SNP) | VAF 12/122 reads (10%) | catalogued as rs1413791008; called by muse, mutect2, varscan2
- OR10D1P | n.427G>A | RNA (SNP) | VAF 45/340 reads (13%) | called by muse, mutect2, varscan2
- OR7D1P | n.660G>T | RNA (SNP) | VAF 63/435 reads (14%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.471G>A | RNA (SNP) | VAF 35/184 reads (19%) | called by muse, mutect2, varscan2
- PCDH11X | c.3033+3684T>A | Intron (SNP) | VAF 51/184 reads (28%) | catalogued as COSV100010359; called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67594G>A | Intron (SNP) | VAF 46/363 reads (13%) | catalogued as rs566924176; called by muse, mutect2, varscan2
- PRDM16 | chr1:3067455 C>T | 5'Flank (SNP) | VAF 51/322 reads (16%) | called by muse, mutect2, varscan2
- PTPRO | c.2712-35C>A | Intron (SNP) | VAF 16/213 reads (8%) | catalogued as rs1419848632; called by muse, mutect2
- REV3L | c.139+10705G>T | Intron (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- RPS4XP21 | n.661del | RNA (DEL) | VAF 42/415 reads (10%) | called by mutect2, pindel, varscan2
- SLC3A2 | chr11:62853701 C>T | 5'Flank (SNP) | VAF 38/390 reads (10%) | called by muse, mutect2
- STMN4 | c.510+737C>T | Intron (SNP) | VAF 36/283 reads (13%) | catalogued as rs1185530806; called by muse, mutect2, varscan2
- TDRD12 | c.-35G>T | 5'UTR (SNP) | VAF 28/175 reads (16%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*276G>T | 3'UTR (SNP) | VAF 70/692 reads (10%) | called by muse, mutect2, varscan2
- THSD4 | c.*3417T>C | 3'UTR (SNP) | VAF 28/240 reads (12%) | catalogued as rs1251517019; called by muse, mutect2, varscan2
- TMEM202 | c.-1G>C | 5'UTR (SNP) | VAF 27/208 reads (13%) | called by muse, mutect2, varscan2
- TMEM254 | c.87+259G>T | Intron (SNP) | VAF 22/206 reads (11%) | called by muse, varscan2
- TPSD1 | chr16:1261358 G>C | 3'Flank (SNP) | VAF 62/538 reads (12%) | called by muse, mutect2, varscan2
- TTBK1 | c.1986+6481G>C | Intron (SNP) | VAF 18/209 reads (9%) | called by muse, mutect2
- TTC3P1 | n.5303C>T | RNA (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- UBE2DNL | n.342C>A | RNA (SNP) | VAF 33/127 reads (26%) | catalogued as rs1385450314; called by muse, mutect2, varscan2
- USH1C | c.1285-7554C>A | Intron (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- WNT7A | c.-49C>G | 5'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- XIRP2 | c.*275G>A | 3'UTR (SNP) | VAF 36/294 reads (12%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+44141G>T | Intron (SNP) | VAF 47/472 reads (10%) | catalogued as rs1200509359; called by muse, mutect2, varscan2
- ZMIZ1 | c.541-173G>T | Intron (SNP) | VAF 62/424 reads (15%) | called by muse, mutect2, varscan2
